Somatic mutation profile of tumor specimen C3N-02027-01 (aliquot CPT0133400011) from CPTAC case C3N-02027, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.9 years (20,045 days).
Specimen C3N-02027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6778116-6f41-4cdd-9ed2-36d6c7d5ae05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02027-71 (Blood Derived Normal), aliquot CPT0133520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec2fd73f-7b61-402f-9516-f11aa308c5de

The open-access MAF lists 2,118 somatic variants for this specimen: 1,412 protein-altering or splice-affecting, 459 silent, 247 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,026, Silent 459, Frame Shift Del 214, Intron 144, Nonsense Mutation 60, Frame Shift Ins 58, 3'UTR 39, RNA 24, Splice Site 23, 5'UTR 20, Splice Region 18, In Frame Del 12.

Variants (750 of 2,118; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1919G>A p.R640H | Missense Mutation (SNP) | VAF 210/610 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs772909106, COSV63973777; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARID3A | c.1669A>G p.S557G | Missense Mutation (SNP) | VAF 60/204 reads (29%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs752338179, COSV55043319; called by muse, mutect2, varscan2
- CACNA1C | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.945); catalogued as rs730880056; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 52/156 reads (33%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- CSF1R | c.2330G>A p.R777Q | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs690016548, CM134453; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 161/390 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HPS4 | c.57del p.L20Ffs*7 | Frame Shift Del (DEL) | VAF 67/293 reads (23%) | catalogued as rs281865097, CD020569; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HRAS | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.215); catalogued as rs727503093, COSV54244375; ClinVar: likely pathogenic; called by muse, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.15844C>T p.R5282* | Nonsense Mutation (SNP) | VAF 72/237 reads (30%) | catalogued as rs587783698, CM126447, COSV56407274; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.646-1_648del p.X216_splice | Splice Site (DEL) | VAF 40/142 reads (28%) | catalogued as rs1553351549; ClinVar: pathogenic; called by mutect2, pindel
- PPP2R1A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 77/234 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205227, CM153572, COSV59042121; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 142/440 reads (32%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 107/317 reads (34%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TINF2 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 65/185 reads (35%) | catalogued as rs1064795632; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 243/666 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRPV4 | c.1774T>C p.F592L | Missense Mutation (SNP) | VAF 36/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs515726158, CM106799; ClinVar: pathogenic; called by muse, mutect2
- USH2A | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 45/122 reads (37%) | catalogued as rs781223647, CM001804, COSV100240460, COSV56332304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ZCCHC8 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1317757765; ClinVar: pathogenic; called by muse, mutect2
- AADACL4 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs374658772; called by muse, mutect2, varscan2
- AASS | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 192/560 reads (34%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.961); catalogued as rs868487258, COSV62790109; called by muse, mutect2, varscan2
- AATK | c.3688_3690del p.K1230del (on ENST00000326724 / NM_001080395.3; = p.K1127del on NM_004920.2) | In Frame Del (DEL) | VAF 46/156 reads (29%) | catalogued as rs757851302; called by pindel, varscan2
- AATK | c.3404del p.G1135Afs*172 (on ENST00000326724 / NM_001080395.3; = p.G1032Afs*172 on NM_004920.2) | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as COSV58365920; called by mutect2, pindel, varscan2
- ABCC3 | c.3833G>A p.R1278H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as rs759534433, COSV53319352; called by muse, mutect2, varscan2
- ABCF1 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); catalogued as COSV58228625; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); catalogued as rs141581474; called by muse, mutect2, varscan2
- ABLIM3 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs754423159, COSV58643995; called by muse, mutect2, varscan2
- AC023055.1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 79/244 reads (32%) | catalogued as rs1429730491, COSV60244581; called by muse, mutect2, varscan2
- ACAD10 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 131/347 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs747732996; called by muse, mutect2, varscan2
- ADAMTS15 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs564922366; called by muse, mutect2, varscan2
- ADAR | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs1193378261, COSV52713908; called by muse, mutect2, varscan2
- ADCY3 | c.1268del p.G423Afs*19 | Frame Shift Del (DEL) | VAF 108/368 reads (29%) | catalogued as rs754914420; ClinVar: risk factor; called by mutect2, pindel, varscan2
- AFAP1L1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs758830317; called by muse, mutect2, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 359/1032 reads (35%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- AIRE | c.652+7G>A | Splice Region (SNP) | VAF 32/72 reads (44%) | catalogued as rs373277723; called by muse, mutect2, varscan2
- AKAP3 | c.1643G>T p.R548L | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1203259746; called by muse, mutect2, varscan2
- AL645922.1 | c.1907G>A p.G636D | Missense Mutation (SNP) | VAF 55/560 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762998024, COSV54960723; called by muse, mutect2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 14/154 reads (9%) | catalogued as rs758955164; called by mutect2, pindel
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 34/236 reads (14%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel, varscan2
- ALDH3A1 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779314973, COSV56737118; called by muse, mutect2, varscan2
- AMER1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57659947; called by muse, mutect2, varscan2
- AMOTL2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 184/508 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs199588964; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 92/344 reads (27%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKEF1 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 49/151 reads (32%) | catalogued as rs775651962, COSV65691971; called by muse, mutect2
- ANKFY1 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs377547904; called by muse, mutect2, varscan2
- ANKRD11 | c.7531G>A p.V2511I | Missense Mutation (SNP) | VAF 126/441 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs777571791, COSV56358590; called by muse, mutect2, varscan2
- ANKRD34A | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553761373; called by muse, mutect2, varscan2
- ANKRD39 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as rs772419724; called by muse, mutect2, varscan2
- ANLN | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs201613256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANOS1 | c.248G>A p.C83Y | Missense Mutation (SNP) | VAF 24/365 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52918172; called by muse, mutect2
- AP4M1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 73/713 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs757999633; ClinVar: uncertain significance; called by muse, mutect2
- APBB1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772042074; called by muse, mutect2, varscan2
- APOB | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 158/502 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.875); catalogued as rs1328964290, COSV51946843; called by muse, mutect2, varscan2
- APOE | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 232/679 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); catalogued as rs372938213; called by muse, mutect2, varscan2
- ARHGAP12 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 53/177 reads (30%) | catalogued as rs774749812, COSV60961747; called by muse, mutect2, varscan2
- ARHGAP5 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61533836; called by muse, mutect2, varscan2
- ARHGAP5 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 30/87 reads (34%) | catalogued as rs765717212, COSV100565239; called by muse, mutect2, varscan2
- ARHGEF10 | c.4067C>T p.A1356V (on ENST00000398564; = p.A1331V on NM_014629.4) | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs142550609; called by muse, mutect2
- ARHGEF18 | c.356C>A p.P119Q (on ENST00000359920 / NM_001130955.2; = p.P15Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV60474333; called by muse, mutect2, varscan2
- ARHGEF2 | c.1957C>T p.R653W (on ENST00000361247 / NM_001162383.2; = p.R625W on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs745316588; called by muse, mutect2
- ARID1A | c.1867G>T p.G623* | Nonsense Mutation (SNP) | VAF 79/220 reads (36%) | catalogued as rs267598525, COSV61386313, COSV61387945; called by muse, mutect2, varscan2
- ARMC5 | c.2561C>T p.A854V | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as rs1334144375, COSV51659007, COSV51660023; called by muse, mutect2
- ARNT | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778405288; called by muse, mutect2, varscan2
- ARRDC4 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99164558; called by muse, mutect2, varscan2
- ASB7 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 89/470 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV58403365; called by muse, mutect2, varscan2
- ASL | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100509025; called by muse, mutect2
- ASPSCR1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs375727115; called by muse, mutect2, varscan2
- ATP2A1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 109/310 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs769076880; called by muse, mutect2, varscan2
- ATP2B3 | c.2132C>T p.T711M | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99051133; called by muse, mutect2, varscan2
- AXIN1 | c.2446A>G p.K816E | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99249971; called by muse, mutect2
- BAG3 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 118/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057524225; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR3 | c.2438G>A p.R813H | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as rs373868471, COSV53073974; called by muse, mutect2, varscan2
- BCAS1 | c.1675G>T p.G559C | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006175; called by muse, mutect2, varscan2
- BCHE | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.107); catalogued as COSV52255254, COSV52261070; called by muse, mutect2, varscan2
- BEAN1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1463602406; called by muse, mutect2, varscan2
- BIRC6 | c.14396G>A p.R4799H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs766026268; called by muse, mutect2, varscan2
- BOP1 | c.2218G>A p.G740R | Missense Mutation (SNP) | VAF 138/632 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1020723782; called by muse, mutect2, varscan2
- BPIFC | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs149092400; called by muse, mutect2, varscan2
- BPTF | c.7051A>G p.T2351A | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as rs559796848; called by muse, mutect2
- BRWD1 | c.6926del p.L2309* | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | catalogued as rs1455506786, COSV59000653; called by pindel, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | catalogued as rs777776928; called by mutect2, varscan2
- BTBD6 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.104); catalogued as rs1332586609, COSV59266929; called by muse, mutect2, varscan2
- BTBD6 | c.947del p.T316Rfs*12 | Frame Shift Del (DEL) | VAF 30/344 reads (9%) | catalogued as COSV59270881; called by mutect2, pindel
- BTBD8 | c.1886dup p.N629Kfs*18 (on ENST00000636805 / NM_001376131.1; = p.N116Kfs*18 on NM_015237.4) | Frame Shift Ins (INS) | VAF 62/188 reads (33%) | catalogued as rs774107642; called by mutect2, pindel, varscan2
- BTN3A1 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 159/476 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV50024764; called by muse, mutect2, varscan2
- BVES | c.977A>G p.Q326R | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.031); catalogued as rs546289053; called by mutect2, varscan2
- C12orf40 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61132330; called by muse, mutect2, varscan2
- C19orf54 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 134/417 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs760049738; called by muse, mutect2, varscan2
- C1orf112 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs763182857, COSV53678044; called by muse, mutect2, varscan2
- C4orf54 | c.4598G>A p.R1533H | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs943183602; called by muse, mutect2, varscan2
- C6orf15 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 89/254 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs1562743845, COSV52538112; called by muse, mutect2, varscan2
- CA5B | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 92/218 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181134647, COSV100590847, COSV59415674; called by muse, mutect2, varscan2
- CABIN1 | c.4116C>T p.D1372= | Splice Region (SNP) | VAF 135/436 reads (31%) | catalogued as rs750110458, COSV54077665; called by muse, mutect2, varscan2
- CABLES2 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs150007624; called by muse, mutect2, varscan2
- CACNA1F | c.4426C>T p.R1476C | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs782690591; called by muse, mutect2, varscan2
- CACNA1H | c.6397C>T p.R2133C | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs765510801, COSV52352507; called by muse, mutect2, varscan2
- CACNA2D4 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 41/118 reads (35%) | catalogued as rs910218315; called by muse, mutect2, varscan2
- CALHM1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 174/547 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.49); catalogued as rs765898547; called by muse, mutect2, varscan2
- CAMSAP1 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs369094948; called by muse, mutect2, varscan2
- CAP2 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs751783366; called by muse, mutect2, varscan2
- CAPN8 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1485837688, COSV64817836; called by muse, mutect2, varscan2
- CARD11 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 132/431 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1402987893, COSV67798094; called by muse, varscan2
- CBY2 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1028284556, COSV60117095; called by muse, mutect2, varscan2
- CCAR1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56272063; called by muse, mutect2, varscan2
- CCDC134 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs762111527; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC180 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs774159388; called by muse, mutect2, varscan2
- CCDC38 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs142050445; called by muse, mutect2
- CCDC40 | c.3180+6C>T | Splice Region (SNP) | VAF 17/177 reads (10%) | catalogued as rs753716586; called by muse, mutect2
- CCDC42 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776086783, COSV99549883; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 33/167 reads (20%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | catalogued as rs747131147; called by mutect2, pindel, varscan2
- CCDC8 | c.1573G>A p.A525T | Missense Mutation (SNP) | VAF 19/198 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs1356491603; called by muse, mutect2
- CCDC83 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752971434; called by muse, mutect2, varscan2
- CCDC87 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs777766804, COSV59579032; called by muse, mutect2, varscan2
- CCDC88B | c.3703C>T p.R1235* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | catalogued as rs771307009; called by muse, mutect2, varscan2
- CCKAR | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs774446786; called by muse, mutect2, varscan2
- CCNO | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 45/340 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.763); catalogued as rs771239201; called by muse, mutect2, varscan2
- CD22 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 22/486 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.253); catalogued as rs1012239591; called by muse, mutect2
- CD22 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369740146; called by muse, mutect2, varscan2
- CD44 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369496409; called by muse, mutect2, varscan2
- CDC14C | c.670A>G p.T224A (on ENST00000428251; = p.T117A on NM_152627.3) | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1461989293; called by muse, mutect2, varscan2
- CDC7 | c.1544A>G p.K515R | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV52312274; called by muse, mutect2
- CDH1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 21/600 reads (4%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.446); catalogued as rs1060501247; ClinVar: uncertain significance; called by muse, mutect2
- CDH2 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs879152118, COSV52280044; called by muse, mutect2
- CEACAM1 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50731437, COSV99362281; called by muse, mutect2
- CELF2 | c.419C>T p.S140L (on ENST00000416382 / NM_001025077.3; = p.S147L on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746403544, COSV59971344; called by muse, mutect2
- CELSR2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs780906021, COSV54768709; called by muse, mutect2, varscan2
- CENPB | c.1085C>T p.T362M | Missense Mutation (SNP) | VAF 135/431 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV60148697; called by muse, mutect2, varscan2
- CEP72 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs768607398; called by muse, mutect2
- CEP76 | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | catalogued as rs1335282149, COSV50869971; called by muse, mutect2, varscan2
- CERS5 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs1402501914; called by muse, mutect2, varscan2
- CERS6 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.407); catalogued as rs1225015319, COSV99986310; called by muse, mutect2, varscan2
- CGN | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148637517; called by muse, mutect2, varscan2
- CHD7 | c.8774C>T p.A2925V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.587); catalogued as rs1563674763; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHPF | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 45/400 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556897436, COSV60536059; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 60/225 reads (27%) | catalogued as rs751548647; called by mutect2, varscan2
- CHST11 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 156/412 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs765591058, COSV57983097, COSV57994169; called by muse, mutect2, varscan2
- CLDN10 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.298); catalogued as COSV54824082; called by muse, mutect2
- CLDN15 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs765578247; called by muse, mutect2, varscan2
- CNOT1 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV55314621; called by muse, mutect2
- CNTN5 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54335040; called by muse, mutect2
- CNTNAP5 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs767854611, COSV70520253; called by muse, mutect2, varscan2
- CNTNAP5 | c.2632C>T p.R878W | Missense Mutation (SNP) | VAF 44/518 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs773503987, COSV70486764; called by muse, mutect2
- COG2 | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs758358715, COSV64188377; called by muse, mutect2, varscan2
- COL4A2 | c.1561G>A p.G521S | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433036701, COSV100847269; called by muse, mutect2, varscan2
- COL5A3 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.53); catalogued as rs753274164; called by muse, mutect2, varscan2
- COL6A3 | c.4271G>A p.R1424H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.093); catalogued as rs149838946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A2 | c.281del p.P94Lfs*143 | Frame Shift Del (DEL) | VAF 34/151 reads (23%) | catalogued as rs1277273445; called by mutect2, pindel, varscan2
- CP | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 127/357 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as rs181428197; called by muse, mutect2, varscan2
- CPA4 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780563559, COSV104382976; called by muse, mutect2, varscan2
- CPEB2 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 138/395 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs570391181; called by muse, mutect2, varscan2
- CPN1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 49/596 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as COSV64942671; called by muse, mutect2
- CPNE1 | c.995+1G>A p.X332_splice (on ENST00000352393; = p.X337_splice on NM_003915.5) | Splice Site (SNP) | VAF 13/73 reads (18%) | catalogued as rs964982391; called by muse, mutect2, varscan2
- CPNE1 | c.253A>G p.T85A (on ENST00000352393; = p.T90A on NM_003915.5) | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as rs938226263; called by muse, mutect2
- CRAMP1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs754112928; called by muse, mutect2, varscan2
- CREB5 | c.214G>A p.V72M (on ENST00000357727 / NM_182898.4; = p.V65M on NM_004904.3) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754514486, COSV100745006; called by muse, mutect2, varscan2
- CROCC2 | c.4766C>T p.A1589V | Missense Mutation (SNP) | VAF 110/359 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.679); catalogued as rs1056618237; called by muse, mutect2, varscan2
- CRYM | c.324+2T>C p.X108_splice | Splice Site (SNP) | VAF 20/369 reads (5%) | catalogued as COSV54830133; called by muse, mutect2
- CSF1R | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.28); catalogued as rs1419926665, COSV53827728; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1594dup p.T532Nfs*31 | Frame Shift Ins (INS) | VAF 116/455 reads (25%) | catalogued as rs778908076; called by mutect2, varscan2
- CSMD1 | c.8017G>A p.E2673K (on ENST00000520002; = p.E2672K on NM_033225.6) | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs762951826, COSV59312630; called by muse, mutect2, varscan2
- CSPP1 | c.3250C>T p.R1084* (on ENST00000676605; = p.R1043* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 64/192 reads (33%) | catalogued as rs200881715, COSV51592502; called by muse, mutect2, varscan2
- CTDSPL2 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV52945031; called by muse, mutect2, varscan2
- CTLA4 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs759232662, COSV55592615; called by muse, mutect2, varscan2
- CTNNB1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs780428505; called by muse, mutect2, varscan2
- CUL7 | c.2674C>T p.L892F | Missense Mutation (SNP) | VAF 14/369 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs868707301; called by muse, mutect2
- CXorf66 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.889); catalogued as rs868819771, COSV65169527; called by muse, mutect2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 58/212 reads (27%) | catalogued as rs751187768; called by mutect2, varscan2
- DAPK1 | c.3307G>A p.V1103I | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200627640; called by muse, mutect2, varscan2
- DBN1 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs200687613; called by muse, mutect2, varscan2
- DCBLD1 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 202/581 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771490256; called by muse, mutect2, varscan2
- DCLK3 | c.1864G>A p.V622M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs568759319; called by muse, varscan2
- DDX18 | c.1872C>T p.N624= | Splice Region (SNP) | VAF 35/123 reads (28%) | catalogued as rs139180096; called by muse, mutect2, varscan2
- DDX39A | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs141207973; called by muse, mutect2, varscan2
- DDX60L | c.3338del p.L1113Cfs*38 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs757771764; called by mutect2, varscan2
- DEAF1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs149746031; called by muse, mutect2
- DEAF1 | c.913_915del p.K305del | In Frame Del (DEL) | VAF 156/540 reads (29%) | catalogued as rs1554943158; called by pindel, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 36/126 reads (29%) | catalogued as rs748318989; called by mutect2, varscan2
- DGKH | c.583_584del p.L196Ffs*14 | Frame Shift Del (DEL) | VAF 48/268 reads (18%) | catalogued as rs1345516910; called by pindel, varscan2
- DGKK | c.361T>C p.S121P | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs868942691; called by muse, mutect2
- DGKZ | c.1344_1345insC p.K449Qfs*17 (on ENST00000454345 / NM_001105540.2; = p.K261Qfs*17 on NM_003646.4) | Frame Shift Ins (INS) | VAF 74/295 reads (25%) | catalogued as COSV58984107, COSV58987748; called by mutect2, pindel, varscan2
- DHX38 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as rs760440239; called by muse, mutect2, varscan2
- DHX57 | c.1775A>C p.K592T | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1305811128, COSV54882286; called by muse, mutect2, varscan2
- DIRAS1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 91/233 reads (39%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.872); catalogued as COSV60216114; called by muse, mutect2, varscan2
- DIS3 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs917054849, COSV66708190; called by muse, mutect2, varscan2
- DLEU7 | c.94del p.D32Tfs*59 | Frame Shift Del (DEL) | VAF 60/192 reads (31%) | catalogued as rs867917062; called by mutect2, pindel, varscan2
- DLG4 | c.1423C>T p.R475W (on ENST00000399506 / NM_001321075.3; = p.R518W on NM_001365.4) | Missense Mutation (SNP) | VAF 107/320 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1431337727; called by muse, mutect2, varscan2
- DLK1 | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs751157855; called by muse, mutect2
- DLK2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as rs752893762; called by muse, mutect2, varscan2
- DMAC2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as rs782665880; called by muse, mutect2
- DNAH1 | c.9244C>T p.R3082C | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs781114057, COSV70231260; called by muse, mutect2
- DNAH5 | c.2093T>C p.V698A | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV54247060; called by muse, mutect2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 53/152 reads (35%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJC28 | c.590C>T p.T197M | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200167967, COSV58721170; called by muse, mutect2, varscan2
- DNMT1 | c.2866G>A p.V956M | Missense Mutation (SNP) | VAF 156/460 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.046); catalogued as rs148038464; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DNMT3A | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1311728146; called by muse, mutect2, varscan2
- DNMT3L | c.626del p.L209Wfs*10 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | catalogued as rs1249070495; called by mutect2, pindel, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 67/323 reads (21%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPH1 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs201399054; called by muse, mutect2, varscan2
- DPYSL5 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 55/418 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.17); catalogued as rs139435744; called by muse, mutect2, varscan2
- DRD4 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 92/530 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.36); catalogued as rs535202297, COSV99448685; called by muse, varscan2
- DSCAML1 | c.3139G>A p.D1047N (on ENST00000321322; = p.D987N on NM_020693.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs753992533, COSV100356298; called by muse, mutect2, varscan2
- DSCAML1 | c.1220G>A p.R407H (on ENST00000321322; = p.R347H on NM_020693.4) | Missense Mutation (SNP) | VAF 180/594 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.765); catalogued as rs759795586, COSV58392501; called by muse, mutect2, varscan2
- DST | c.17566G>A p.A5856T (on ENST00000361203 / NM_001374722.1; = p.A3553T on NM_015548.5) | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as rs540680338; called by muse, mutect2, varscan2
- DUOX2 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 202/581 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs145586290; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 32/119 reads (27%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECT2L | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs755043557; called by muse, mutect2
- EDA2R | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 22/230 reads (10%) | catalogued as COSV53630746; called by muse, mutect2
- EDC4 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); catalogued as rs950647162, COSV62766483; called by muse, mutect2, varscan2
- EEF2K | c.1702G>A p.V568M | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs750302565; called by muse, mutect2, varscan2
- EFCAB5 | c.3746C>T p.T1249M | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.921); catalogued as rs781519608, COSV57927106; called by muse, mutect2, varscan2
- EFCAB6 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 54/214 reads (25%) | catalogued as rs377471989; called by muse, mutect2, varscan2
- EHD4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs145717011; called by muse, mutect2
- EIF2AK4 | c.2000C>T p.T667M | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs760005119; called by muse, mutect2, varscan2
- EIF3A | c.3260G>T p.R1087L | Missense Mutation (SNP) | VAF 196/655 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64963410; called by muse, varscan2
- EIF3A | c.2759G>A p.R920H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1311948696; called by muse, mutect2, varscan2
- EIF3D | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53403492; called by muse, mutect2, varscan2
- ELF3 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 82/515 reads (16%) | catalogued as COSV100668966; called by muse, mutect2, varscan2
- EMILIN1 | c.1353dup p.L452Afs*57 | Frame Shift Ins (INS) | VAF 30/66 reads (45%) | catalogued as rs763633527; called by mutect2, varscan2
- ENO4 | c.1759del p.Y587Tfs*31 (on ENST00000622726; = p.Y584Tfs*31 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 16/100 reads (16%) | catalogued as rs763733545, COSV53387848; called by mutect2, varscan2
- EP400 | c.8407G>A p.A2803T | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.307); catalogued as rs936464848; called by muse, mutect2, varscan2
- EPG5 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as rs372940918, CM149945; called by muse, mutect2, varscan2
- EPHA4 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56035082; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 16/93 reads (17%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EPOR | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs771039244, COSV55801009; called by muse, mutect2, varscan2
- ERBIN | c.3830del p.P1277Lfs*14 (on ENST00000284037 / NM_001253697.2; = p.P1236Lfs*14 on NM_018695.4) | Frame Shift Del (DEL) | VAF 109/386 reads (28%) | catalogued as rs781559768; called by mutect2, pindel, varscan2
- ERCC6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 235/756 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100876052; called by muse, mutect2, varscan2
- ERMARD | c.444C>A p.C148* | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | catalogued as COSV64649634; called by muse, mutect2
- ESPL1 | c.4280G>A p.R1427Q | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1474921932; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 50/336 reads (15%) | catalogued as rs775950025; called by mutect2, varscan2
- EVC2 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV60404764; called by muse, mutect2, varscan2
- EVI5 | c.1222dup p.M408Nfs*5 | Frame Shift Ins (INS) | VAF 22/78 reads (28%) | catalogued as rs760182064; called by mutect2, varscan2
- EVPL | c.2779C>T p.R927W | Missense Mutation (SNP) | VAF 162/450 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs771495391, COSV56914288; called by muse, mutect2, varscan2
- EXOC3L4 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 134/339 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs761841045; called by muse, mutect2, varscan2
- EXOC7 | c.2054G>A p.R685H (on ENST00000335146 / NM_001145297.4; = p.R603H on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763431511; called by muse, mutect2, varscan2
- EXT2 | c.497G>A p.R166H (on ENST00000343631; = p.R199H on NM_000401.3) | Missense Mutation (SNP) | VAF 100/303 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs772821141, COSV59147557; called by muse, mutect2, varscan2
- FAAP100 | c.2587G>A p.A863T | Missense Mutation (SNP) | VAF 64/217 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs778557641; called by muse, mutect2, varscan2
- FADS3 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs758937836; called by muse, mutect2, varscan2
- FAM131A | c.715C>T p.R239W (on ENST00000310585; = p.R270W on NM_144635.5) | Missense Mutation (SNP) | VAF 83/212 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs779128770, COSV55599756, COSV55603564; called by muse, mutect2, varscan2
- FAM149B1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs766353650; called by muse, mutect2, varscan2
- FAM168B | c.305C>T p.T102M | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.235); catalogued as rs762063773, COSV101112208; called by muse, mutect2, varscan2
- FAM171A1 | c.2504C>T p.T835M | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); catalogued as rs1482241961; called by muse, mutect2, varscan2
- FAM189A1 | c.728del p.P243Hfs*71 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | catalogued as COSV99720881; called by mutect2, pindel, varscan2
- FAM47C | c.2824T>C p.Y942H | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1180359944, COSV100792613; called by muse, mutect2
- FAM71D | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs764978597; called by muse, mutect2, varscan2
- FAM83E | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs543968839, COSV54372060; called by muse, mutect2, varscan2
- FAN1 | c.2470C>T p.R824C | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs199532729; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | catalogued as rs746983128; called by mutect2, varscan2
- FARP2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 34/484 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs371446032; called by muse, mutect2
- FASTKD1 | c.10dup p.T4Nfs*34 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | catalogued as rs771228336; called by mutect2, varscan2
- FAT2 | c.9562C>T p.R3188C | Missense Mutation (SNP) | VAF 42/490 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55826239; called by muse, mutect2
- FBN2 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 183/512 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs150506063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXW5 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 134/426 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.312); catalogued as rs572255649; called by muse, mutect2, varscan2
- FBXW5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 201/558 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148314608; called by muse, mutect2, varscan2
- FBXW7 | c.1800T>A p.D600E (on ENST00000281708 / NM_001349798.2; = p.D520E on NM_018315.5) | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55960622; called by muse, mutect2, varscan2
- FBXW7 | c.1429G>A p.G477S (on ENST00000281708 / NM_001349798.2; = p.G397S on NM_018315.5) | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55891932; called by muse, mutect2, varscan2
- FBXW8 | c.842G>A p.G281D (on ENST00000309909; = p.G319D on NM_012174.1) | Missense Mutation (SNP) | VAF 163/510 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.422); catalogued as rs140698430; called by muse, mutect2, varscan2
- FBXW9 | c.1085G>A p.R362H (on ENST00000587955; = p.R342H on NM_032301.3) | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs766426225, COSV100982023; called by muse, mutect2, varscan2
- FCHO1 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 124/347 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359266297; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR3 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 125/647 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775174456; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIBCD1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs749509642; called by muse, mutect2, varscan2
- FIG4 | c.2340G>T p.K780N | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV57791728; called by muse, mutect2, varscan2
- FILIP1L | c.1981C>T p.R661* (on ENST00000354552 / NM_182909.3; = p.R421* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/130 reads (35%) | catalogued as rs771815841, COSV58767876; called by muse, mutect2, varscan2
- FIZ1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs1210262665; called by muse, mutect2, varscan2
- FMNL3 | c.28del p.V10Sfs*33 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs35397383; called by mutect2, pindel
- FOLR1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100398613; called by muse, mutect2, varscan2
- FOXA1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51646069, COSV51650867; called by muse, mutect2, varscan2
- FOXA3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as rs746646287, COSV56215998; called by muse, mutect2, varscan2
- FREM2 | c.8986G>A p.D2996N | Missense Mutation (SNP) | VAF 154/445 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs370936866, COSV54835373; called by muse, mutect2, varscan2
- FUT4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62469438; called by muse, mutect2, varscan2
- FXR2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs868617231, COSV104376215; called by muse, mutect2, varscan2
- FXYD2 | c.65-5C>T | Splice Region (SNP) | VAF 31/247 reads (13%) | catalogued as rs1407414708; called by muse, mutect2, varscan2
- FZD10 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1043239293, COSV57473174; called by muse, mutect2, varscan2
- GATA5 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs753656900; called by muse, mutect2, varscan2
- GCN1 | c.4099G>A p.V1367M | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs769007980; called by muse, mutect2, varscan2
- GDE1 | c.88A>G p.N30D | Missense Mutation (SNP) | VAF 127/353 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs773829743; called by muse, mutect2, varscan2
- GFOD2 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1167669804; called by muse, mutect2, varscan2
- GGT5 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 65/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs146114235; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 50/138 reads (36%) | catalogued as rs749150409; called by mutect2, varscan2
- GMIP | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as COSV52556428; called by muse, mutect2
- GPR137 | c.138G>A p.W46* | Nonsense Mutation (SNP) | VAF 10/231 reads (4%) | catalogued as COSV57403326; called by muse, mutect2
- GPR31 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 150/352 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs780885378, COSV64761204; called by muse, mutect2, varscan2
- GPR34 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs764448245; called by muse, mutect2, varscan2
- GPRC5A | c.865G>A p.V289M | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768305277; called by muse, mutect2
- GPT | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 183/433 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1267529960, COSV52952224; called by muse, mutect2, varscan2
- GRAP2 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs775800288; called by muse, mutect2, varscan2
- GRIK5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs201959426; called by muse, mutect2, varscan2
- GRIN1 | c.2297G>A p.S766N | Missense Mutation (SNP) | VAF 22/624 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV59298636; called by muse, mutect2
- GSN | c.1939G>A p.G647R | Missense Mutation (SNP) | VAF 48/547 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141082919, COSV100376494; called by muse, mutect2
- GSPT2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.129); catalogued as rs781925454; called by muse, mutect2, varscan2
- GUCY1A2 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs753774502, COSV56477850; called by muse, mutect2, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 13/118 reads (11%) | catalogued as COSV54945907; called by mutect2, varscan2
- HDAC4 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 243/689 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as rs770934590, COSV61860474; called by muse, mutect2, varscan2
- HDAC9 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs367766754; called by muse, mutect2, varscan2
- HDDC3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV104398088; called by muse, mutect2, varscan2
- HECTD1 | c.1447+2T>C p.X483_splice | Splice Site (SNP) | VAF 23/118 reads (19%) | catalogued as rs1183528697; called by muse, mutect2, varscan2
- HELLS | c.461del p.N154Ifs*29 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | catalogued as rs775038246; called by mutect2, varscan2
- HELZ | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 123/374 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as rs1258280006; called by muse, mutect2, varscan2
- HELZ2 | c.5006C>T p.T1669M (on ENST00000467148 / NM_001037335.2; = p.T1100M on NM_033405.3) | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1296283970; called by muse, mutect2, varscan2
- HFM1 | c.3100G>A p.G1034S | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54025078; called by muse, mutect2, varscan2
- HGFAC | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs199995558, COSV66977337; called by muse, mutect2, varscan2
- HIC2 | c.481dup p.R161Pfs*40 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | catalogued as rs745918762; called by mutect2, varscan2
- HK3 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 135/513 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs755568515, COSV52846463; called by muse, mutect2, varscan2
- HLA-B | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 70/632 reads (11%) | catalogued as rs151341185, CM1412118; called by muse, varscan2
- HLA-DMA | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs779711764, COSV66385643; called by muse, mutect2, varscan2
- HMCN1 | c.6308C>T p.P2103L | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs768441829, COSV54878232; called by muse, mutect2, varscan2
- HMGCR | c.383del p.F128Sfs*4 | Frame Shift Del (DEL) | VAF 58/215 reads (27%) | catalogued as COSV55315639; called by mutect2, pindel, varscan2
- HMGCS1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 18/157 reads (11%) | catalogued as rs777760218; called by muse, mutect2, varscan2
- HNRNPR | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV56421119; called by muse, mutect2, varscan2
- HOMER3 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.442); catalogued as rs746165698; called by muse, mutect2, varscan2
- HPD | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs189210271; called by muse, mutect2
- HS3ST1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459315322; called by muse, mutect2, varscan2
- HSPB1 | c.438del p.G147Vfs*17 | Frame Shift Del (DEL) | VAF 162/612 reads (26%) | catalogued as rs747325717; called by mutect2, pindel, varscan2
- HSPG2 | c.3748G>A p.A1250T | Missense Mutation (SNP) | VAF 152/393 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs779841547, COSV65973965; called by muse, mutect2, varscan2
- HTR1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs1260684033, COSV60499881; called by muse, mutect2
- HUS1B | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 79/458 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100032458; called by muse, mutect2, varscan2
- HUWE1 | c.2959G>A p.G987R | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs1179696036, COSV53360441, COSV99472876; called by muse, mutect2, varscan2
- HYAL2 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63306418; called by muse, mutect2, varscan2
- IBTK | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.324); catalogued as COSV60393075; called by muse, mutect2, varscan2
- IGF2 | c.686dup p.E230Rfs*50 (on ENST00000434045 / NM_001127598.3; = p.E174Rfs*50 on NM_000612.6) | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 84/294 reads (29%) | catalogued as rs760021495; called by mutect2, varscan2
- IGSF22 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs1173666971; called by muse, mutect2, varscan2
- IGSF9B | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765281579; called by muse, mutect2, varscan2
- IL17REL | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs773742457, COSV100377490; called by muse, mutect2
- IL1R2 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769630697, COSV60207166; called by muse, mutect2
- INCENP | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs187738543; called by muse, mutect2, varscan2
- INF2 | c.3611C>T p.S1204L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs376222605; called by muse, mutect2, varscan2
- INO80D | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 18/167 reads (11%) | catalogued as rs1211499408; called by muse, mutect2, varscan2
- INPP5K | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs753699839; called by muse, mutect2
- INPPL1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771815535, COSV53357347; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 65/232 reads (28%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS1 | c.5561C>T p.A1854V | Missense Mutation (SNP) | VAF 45/361 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs373812497; called by muse, mutect2, varscan2
- INTS1 | c.4310G>A p.R1437H | Missense Mutation (SNP) | VAF 41/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs567015657; called by muse, mutect2, varscan2
- INTS11 | c.146_148del p.S49del | In Frame Del (DEL) | VAF 69/252 reads (27%) | catalogued as rs777963213; called by mutect2, pindel, varscan2
- IPO4 | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs774780934; called by muse, mutect2, varscan2
- IPO9 | c.944_946del p.E315del | In Frame Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs1170170682; called by pindel, varscan2
- ISL1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 155/428 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57933015, COSV57934791; called by muse, mutect2, varscan2
- ITGA3 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs376118706; called by muse, mutect2, varscan2
- ITGB8 | c.*5del | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | catalogued as rs770665724; called by mutect2, pindel, varscan2
- JAG1 | c.2288G>A p.G763D | Missense Mutation (SNP) | VAF 171/461 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99653399; called by muse, mutect2, varscan2
- JAG2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 189/539 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs140813175; called by muse, mutect2, varscan2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | catalogued as rs1181132297; called by mutect2, pindel
- JPH2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 47/448 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1336861206, COSV65902735; called by muse, mutect2, varscan2
- KANK2 | c.1050del p.A351Hfs*14 | Frame Shift Del (DEL) | VAF 54/187 reads (29%) | catalogued as COSV100763198; called by mutect2, pindel, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 33/195 reads (17%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNA5 | c.1021G>A p.V341M | Missense Mutation (SNP) | VAF 96/281 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as rs370821881; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 27/226 reads (12%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNG2 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143557627; called by muse, varscan2
- KCNK4 | c.969dup p.E324Rfs*104 | Frame Shift Ins (INS) | VAF 60/216 reads (28%) | catalogued as rs775736273; called by mutect2, pindel, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 74/220 reads (34%) | catalogued as rs753256170; called by mutect2, varscan2
- KCNS1 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 81/272 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60261389; called by muse, mutect2, varscan2
- KCP | c.4025G>A p.R1342H (on ENST00000620378; = p.R1466H on NM_001366122.1) | Missense Mutation (SNP) | VAF 39/345 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as rs771179921; called by muse, mutect2, varscan2
- KCP | c.2279C>T p.P760L (on ENST00000620378; = p.P820L on NM_001366122.1) | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1214473265; called by muse, mutect2, varscan2
- KCTD8 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.771); catalogued as rs754419042; called by muse, mutect2
- KDM3B | c.3193C>T p.R1065C | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs539384678, COSV58696020; called by muse, mutect2, varscan2
- KDM6B | c.3380G>A p.R1127Q | Missense Mutation (SNP) | VAF 103/342 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs751637686; called by muse, mutect2, varscan2
- KHDRBS3 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as rs1173128434, COSV63424392; called by muse, mutect2, varscan2
- KHK | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 20/413 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1173075290, COSV53150316; called by muse, mutect2
- KIF26A | c.3282del p.L1096Wfs*152 | Frame Shift Del (DEL) | VAF 22/185 reads (12%) | catalogued as rs745639630; called by mutect2, pindel, varscan2
- KIF26B | c.4927G>A p.G1643S | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1337665637; called by muse, mutect2
- KIF26B | c.5157del p.S1720Afs*16 | Frame Shift Del (DEL) | VAF 104/374 reads (28%) | catalogued as rs1385639497; called by mutect2, pindel, varscan2
- KMT2B | c.1549del p.S517Afs*5 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as COSV52889422, COSV99386062; called by mutect2, pindel, varscan2
- KMT2C | c.6754C>T p.Q2252* | Nonsense Mutation (SNP) | VAF 9/211 reads (4%) | catalogued as COSV51417010; called by muse, mutect2
- KNTC1 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 199/552 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1355792139; called by muse, mutect2, varscan2
- KRAS | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 97/294 reads (33%) | catalogued as rs200186819; called by muse, mutect2, varscan2
- KRT13 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); catalogued as rs762660600; called by muse, mutect2
- KRT8 | c.1034C>G p.A345G | Missense Mutation (SNP) | VAF 45/578 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as rs941654453; called by muse, mutect2
- KRTAP2-2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1233562483; called by muse, mutect2, varscan2
- KRTAP3-2 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs147430362; called by muse, mutect2
- L3MBTL1 | c.2377C>T p.R793C (on ENST00000418998 / NM_001377303.1; = p.R703C on NM_015478.7) | Missense Mutation (SNP) | VAF 128/360 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs888078814, COSV64228831; called by muse, varscan2
- LAMC3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 174/491 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774775769, COSV100735953; called by muse, mutect2, varscan2
- LARP1 | c.724G>A p.G242R (on ENST00000518297 / NM_033551.3; = p.G165R on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.089); catalogued as COSV60424864; called by muse, mutect2, varscan2
- LDLRAP1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs764804901, COSV65473433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGI4 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs751184208; called by muse, mutect2, varscan2
- LIMS1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs776581560; called by muse, mutect2, varscan2
- LIN28B | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); catalogued as rs1288622126; called by muse, mutect2, varscan2
- LLGL2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs754950482, COSV51417683; called by muse, mutect2, varscan2
- LMTK2 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs182143351; called by muse, mutect2, varscan2
- LONP1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 78/429 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs200781774, COSV100638791; called by muse, mutect2, varscan2
- LONRF3 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as rs779776902, COSV59152780; called by muse, mutect2, varscan2
- LOXHD1 | c.2770C>T p.R924W | Missense Mutation (SNP) | VAF 258/763 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs886053832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRIT3 | c.1179del p.T394Hfs*33 | Frame Shift Del (DEL) | VAF 103/329 reads (31%) | catalogued as COSV59984945; called by mutect2, pindel, varscan2
- LZIC | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV101021290; called by muse, mutect2
- LZTR1 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1346699262, COSV53151687; called by muse, mutect2
- MAGI3 | c.3086G>A p.R1029Q | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs367702082; called by muse, mutect2, varscan2
- MAN1C1 | c.1296del p.L433* | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs759630213; called by mutect2, varscan2
- MAP4K4 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV56327733; called by muse, mutect2, varscan2
- MARVELD3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs1458856965, COSV51704066, COSV51705229; called by muse, mutect2, varscan2
- MBOAT7 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.143); catalogued as rs759699339, COSV55474433; called by muse, mutect2, varscan2
- MECOM | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs878869476; called by muse, mutect2, varscan2
- MED12L | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs376454271; called by muse, mutect2, varscan2
- MEF2D | c.606G>A p.A202= | Splice Region (SNP) | VAF 76/287 reads (26%) | catalogued as rs763029801, COSV61730080; called by muse, mutect2, varscan2
- METAP1 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 27/233 reads (12%) | catalogued as rs776502995; called by muse, mutect2, varscan2
- MFSD6 | c.2302G>A p.A768T | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs749919012, COSV55623981; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 25/50 reads (50%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 44/253 reads (17%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MKI67 | c.6772C>T p.R2258* | Nonsense Mutation (SNP) | VAF 34/416 reads (8%) | catalogued as rs150193478, COSV64072473; called by muse, mutect2
- MKNK2 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs866566834; called by muse, mutect2, varscan2
- MOV10 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 41/352 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV62492307; called by muse, mutect2, varscan2
- MPP2 | c.1235G>A p.R412Q (on ENST00000461854 / NM_001278372.2; = p.R388Q on NM_005374.5) | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs377355247, COSV99290658; called by muse, mutect2, varscan2
- MROH1 | c.1865C>T p.A622V | Missense Mutation (SNP) | VAF 219/741 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1238923822; called by muse, mutect2, varscan2
- MROH1 | c.3832G>A p.G1278S | Missense Mutation (SNP) | VAF 197/510 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs998359872; called by muse, mutect2, varscan2
- MRTFA | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs765710534, COSV62936026; called by muse, mutect2, varscan2
- MSANTD1 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278041141; called by muse, mutect2, varscan2
- MSH6 | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750119, CD103561, CD143597, CM1411645, COSV52278636; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MSL1 | c.800G>A p.R267Q (on ENST00000398532 / NM_001365919.1; = p.R4Q on NM_001012241.2) | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1367096563, COSV100278004; called by muse, mutect2, varscan2
- MSR1 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 72/446 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481887954; called by muse, mutect2, varscan2
- MTX1 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs776764435, COSV57428127; called by muse, mutect2, varscan2
- MUC17 | c.11165G>A p.S3722N | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs1261043871; called by muse, mutect2, varscan2
- MUC4 | c.2647G>A p.G883R | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.955); catalogued as COSV100640142; called by muse, mutect2
- MUC5AC | c.14195C>T p.P4732L | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs80315560; called by muse, mutect2, varscan2
- MUC5B | c.2812G>A p.V938I | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs370402303; called by muse, mutect2, varscan2
- MUCL3 | c.1240G>A p.E414K (on ENST00000304311; = p.E1290K on NM_080870.4) | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.688); catalogued as rs1255410490; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 62/236 reads (26%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPC1 | c.2215C>T p.R739C (on ENST00000550270 / NM_206820.2; = p.R764C on NM_002465.4) | Missense Mutation (SNP) | VAF 175/563 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279597195, COSV62252195; called by muse, mutect2, varscan2
- MYCBP2 | c.3449G>A p.R1150Q (on ENST00000357337; = p.R1188Q on NM_015057.5) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs765205497; called by muse, mutect2, varscan2
- MYH14 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1454443536; called by muse, mutect2, varscan2
- MYH9 | c.4333_4335del p.K1445del | In Frame Del (DEL) | VAF 96/342 reads (28%) | catalogued as rs889313598; called by pindel, varscan2
- MYO15B | c.8373dup p.R2792Afs*9 | Frame Shift Ins (INS) | VAF 34/236 reads (14%) | catalogued as rs1568233665; called by mutect2, pindel, varscan2
- MYO18A | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs547643266, COSV62867459; called by muse, mutect2, varscan2
- MYO6 | c.2939G>A p.R980H | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.386); catalogued as rs375397461; called by muse, mutect2, varscan2
- MYO9B | c.5906G>A p.R1969Q | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.343); catalogued as rs748755454; called by muse, mutect2, varscan2
- NANS | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as rs774880374; called by muse, mutect2
- NBPF10 | c.11065del p.R3689Efs*32 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | catalogued as rs781875736; called by mutect2, varscan2
- NCAPG2 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as rs966051610, COSV51985518; called by muse, mutect2
- NCEH1 | c.1087C>T p.R363C (on ENST00000538775; = p.R323C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs754711926, COSV56438285; called by muse, mutect2, varscan2
- NCOA1 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV56052360; called by muse, varscan2
- NCOR1 | c.6923G>A p.R2308Q | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs202234006; called by muse, mutect2, varscan2
- NCOR2 | c.5714G>A p.R1905H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.989); catalogued as rs777477283; called by muse, mutect2, varscan2
- NDC80 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs754583866; called by muse, mutect2, varscan2
- NEURL4 | c.3799del p.V1267* | Frame Shift Del (DEL) | VAF 43/125 reads (34%) | catalogued as rs1202163680; called by mutect2, pindel, varscan2
- NFATC4 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.885); catalogued as rs187429426; called by muse, mutect2, varscan2
- NGLY1 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.174); catalogued as rs1023362606; called by muse, mutect2, varscan2
- NID1 | c.1348C>A p.P450T | Missense Mutation (SNP) | VAF 84/243 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748143607; called by muse, mutect2, varscan2
- NID2 | c.3718C>T p.R1240* | Nonsense Mutation (SNP) | VAF 48/119 reads (40%) | catalogued as rs756743057; called by muse, mutect2, varscan2
- NINL | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs1204939688; called by muse, mutect2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 79/240 reads (33%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NISCH | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs745490517, COSV61900384; called by muse, mutect2, varscan2
- NKD1 | c.862dup p.R288Pfs*12 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | catalogued as rs772439983; called by mutect2, varscan2
- NKX2-3 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1023512386; called by muse, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs753934412; called by mutect2, pindel, varscan2
- NOP2 | c.725G>A p.R242Q (on ENST00000322166 / NM_001258308.2; = p.R238Q on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370611159; called by muse, mutect2, varscan2
- NOTCH1 | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs1440584630; called by muse, mutect2, varscan2
- NOTCH3 | c.5005C>T p.R1669C | Missense Mutation (SNP) | VAF 178/526 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1245716605; called by muse, mutect2, varscan2
- NOTCH3 | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 187/558 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99655423; called by muse, mutect2, varscan2
- NPFF | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99908443; called by muse, mutect2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs774343392; called by mutect2, varscan2
- NRK | c.750G>T p.M250I | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54604621; called by muse, mutect2, varscan2
- NSD3 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV57621522; called by muse, mutect2, varscan2
- NSFL1C | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 16/188 reads (9%) | catalogued as COSV53794235; called by muse, mutect2
- NTM | c.936T>C p.G312= | Splice Region (SNP) | VAF 8/172 reads (5%) | catalogued as rs1393264927; called by muse, mutect2
- NUP155 | c.1157C>T p.T386M (on ENST00000231498 / NM_153485.3; = p.T327M on NM_004298.4) | Missense Mutation (SNP) | VAF 80/232 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs368991435; called by muse, mutect2, varscan2
- NUP188 | c.4526G>A p.G1509D | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV65331176; called by muse, mutect2, varscan2
- NUP210L | c.2072del p.L691Wfs*3 | Frame Shift Del (DEL) | VAF 148/396 reads (37%) | catalogued as rs760869296; called by mutect2, varscan2
- OAF | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1418172517, COSV100202929; called by muse, mutect2, varscan2
- OBSCN | c.18823G>A p.G6275R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs751235211; called by muse, mutect2, varscan2
- ODAPH | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 126/336 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756454916, COSV61140864, COSV61141580; called by muse, mutect2, varscan2
- OGA | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 86/268 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV100761943; called by muse, varscan2
- OPRD1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 160/415 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750038268, COSV52382335; called by muse, mutect2, varscan2
- OR10Z1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV63524917; called by muse, mutect2, varscan2
- OR2A7 | c.385del p.L129Sfs*7 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1243457043; called by mutect2, varscan2
- OR2B11 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV59509298; called by muse, mutect2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 98/368 reads (27%) | catalogued as rs755413956; called by mutect2, varscan2
- OS9 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775835044; called by muse, mutect2, varscan2
- OTOG | c.2947G>A p.A983T | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs897016393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTUD7A | c.2548G>A p.A850T (on ENST00000307050 / NM_001382637.1; = p.A843T on NM_130901.3) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1291030364; called by muse, mutect2, varscan2
- P2RY8 | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.07); catalogued as rs1255191613; called by muse, mutect2
- PANX3 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as rs777601144, COSV52511591; called by muse, mutect2, varscan2
- PAPOLG | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV99474523; called by muse, mutect2
- PAPSS1 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs999491751, COSV54493909; called by muse, mutect2, varscan2
- PAQR9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV100503752; called by muse, mutect2, varscan2
- PARP4 | c.2900G>A p.R967Q | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs554048244; called by muse, mutect2, varscan2
- PCDH19 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 180/578 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55259138; called by muse, mutect2, varscan2
- PCDH7 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV62338402; called by muse, mutect2, varscan2
- PCDHB13 | c.2168G>A p.G723D | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV53401948; called by muse, mutect2
- PCDHB5 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 29/564 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1554276221; called by muse, mutect2
- PCDHGA10 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 219/635 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs777981621, COSV53933301; called by muse, mutect2, varscan2
- PCDHGA5 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.087); catalogued as rs1482984712, COSV54022477; called by muse, mutect2, varscan2
- PCDHGC4 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs1431906047; called by muse, mutect2, varscan2
- PCF11 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV104403291; called by muse, mutect2, varscan2
- PCSK6 | c.2388T>A p.N796K | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs774145990; called by muse, mutect2, varscan2
- PDE6C | c.902T>C p.V301A | Missense Mutation (SNP) | VAF 47/453 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as COSV101008851; called by muse, mutect2, varscan2
- PDK2 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs948527534; called by muse, mutect2, varscan2
- PDLIM5 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.288); catalogued as rs374739373; called by muse, mutect2, varscan2
- PDZD7 | c.166del p.R56Afs*81 | Frame Shift Del (DEL) | VAF 105/366 reads (29%) | catalogued as COSV56519696; called by pindel, varscan2
- PDZD7 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 208/534 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs201178589; called by muse, varscan2
- PER1 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as rs1468429016; called by muse, mutect2
- PER2 | c.2507C>T p.T836M | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs201200083; called by muse, mutect2, varscan2
- PFKL | c.1182del p.K395Rfs*11 | Frame Shift Del (DEL) | VAF 60/195 reads (31%) | catalogued as rs777709620; called by mutect2, pindel, varscan2
- PFKP | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268502751, COSV66895222; called by muse, mutect2
- PGAP6 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs779082879; called by muse, mutect2, varscan2
- PGAP6 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 74/250 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs747731323, COSV51738676; called by muse, mutect2, varscan2
- PGM3 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs748755438, COSV99392517; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PI16 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65448449; called by muse, mutect2
- PI4KA | c.6152G>A p.G2051D | Missense Mutation (SNP) | VAF 76/520 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55408071; called by mutect2, varscan2
- PIGA | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61237682; called by muse, mutect2, varscan2
- PITPNM1 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs766305895, COSV54160800; called by muse, mutect2, varscan2
- PITPNM1 | c.2794C>A p.P932T | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV54161030; called by muse, mutect2
- PITPNM1 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs770744580, COSV62708171; called by muse, mutect2, varscan2
- PITPNM1 | c.2006C>A p.P669Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV62707766; called by muse, mutect2, varscan2
- PIWIL2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs368245312; called by muse, mutect2, varscan2
- PKD1 | c.9880G>A p.A3294T | Missense Mutation (SNP) | VAF 150/916 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1265262304; called by mutect2, varscan2
- PKD2L2 | c.1793dup p.L598Ffs*82 (on ENST00000508883 / NM_001300921.2; = p.L576Ffs*46 on NM_001258448.2) | Frame Shift Ins (INS) | VAF 44/132 reads (33%) | catalogued as rs772923915; called by mutect2, varscan2
- PLA1A | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs367924819; called by muse, mutect2, varscan2
- PLAC8L1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558041885; called by muse, mutect2, varscan2
- PLCD4 | c.259dup p.L87Pfs*24 | Frame Shift Ins (INS) | VAF 88/544 reads (16%) | catalogued as rs770154694; called by mutect2, pindel, varscan2
- PLEC | c.5333C>T p.A1778V (on ENST00000322810 / NM_201380.4; = p.A1668V on NM_000445.5) | Missense Mutation (SNP) | VAF 83/595 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1554700268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG2 | c.3964dup p.Q1322Pfs*19 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs551236586; called by mutect2, varscan2
- PLEKHG5 | c.2360+4C>T | Splice Region (SNP) | VAF 98/318 reads (31%) | catalogued as rs751575330; ClinVar: uncertain significance; called by muse, varscan2
- PLEKHH3 | c.957del p.L321Sfs*19 | Frame Shift Del (DEL) | VAF 51/184 reads (28%) | catalogued as rs1258105672, COSV53188481; called by mutect2, pindel, varscan2
- PLEKHM3 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201443678; called by muse, mutect2, varscan2
- PLOD3 | c.975del p.D326Tfs*32 | Frame Shift Del (DEL) | VAF 22/162 reads (14%) | catalogued as rs777393176; called by mutect2, varscan2
- PLPPR4 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767680963, COSV64565048; called by muse, mutect2, varscan2
- POLR1D | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 121/361 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1014369151, CM108857, COSV57256177; called by muse, mutect2, varscan2
- POLRMT | c.2446C>A p.L816M | Missense Mutation (SNP) | VAF 19/702 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1323719673; called by muse, mutect2
- POMGNT2 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); catalogued as rs752449605; called by muse, mutect2, varscan2
- POTEI | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1341938232, COSV71576145; called by mutect2, varscan2
- POU4F3 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 146/395 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs1048744959, COSV57945165; called by muse, mutect2, varscan2
- PPP5C | c.46dup p.R16Pfs*7 | Frame Shift Ins (INS) | VAF 24/238 reads (10%) | catalogued as rs766639242; called by mutect2, varscan2
- PPT2 | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs945364426, COSV99278676; called by muse, mutect2, varscan2
- PROSER2 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as rs145971555; called by muse, mutect2, varscan2
- PRR35 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1310397026; called by muse, mutect2, varscan2
- PRRC2C | c.1399C>T p.R467W (on ENST00000367742; = p.R465W on NM_015172.4) | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281668603; called by muse, mutect2
- PRUNE2 | c.3305C>T p.T1102I | Missense Mutation (SNP) | VAF 117/307 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as rs377727228; called by muse, mutect2, varscan2
- PSD4 | c.1837_1838+1del | In Frame Del (DEL) | VAF 38/140 reads (27%) | catalogued as rs751014443; called by pindel, varscan2
- PSG3 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs138127977, COSV59506582; called by muse, mutect2, varscan2
- PSMD4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as rs943122880; called by muse, mutect2, varscan2
- PTCH1 | c.3936G>A p.W1312* | Nonsense Mutation (SNP) | VAF 18/287 reads (6%) | catalogued as COSV59477211; called by muse, mutect2
- PTPN7 | c.1007C>T p.T336M (on ENST00000495688; = p.T375M on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781093850; called by muse, mutect2, varscan2
- PTPRA | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 126/349 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs375070304; called by muse, mutect2, varscan2
- PTPRJ | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs371829286; called by muse, mutect2, varscan2
- PWWP2B | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs750701942, COSV100535987; called by muse, mutect2, varscan2
- PXDN | c.3446C>T p.T1149M | Missense Mutation (SNP) | VAF 151/391 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs868152484; called by muse, mutect2, varscan2
- PXDNL | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.389); catalogued as rs757076660, COSV62480016; called by muse, mutect2, varscan2
- RAB3A | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs771003611, COSV55853135; called by muse, mutect2
- RAB3IL1 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758777730; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 70/225 reads (31%) | catalogued as rs767679528; called by mutect2, pindel, varscan2
- RASGEF1C | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 133/438 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as rs376754942; called by muse, mutect2, varscan2
- RB1 | c.13del p.T5Pfs*60 | Frame Shift Del (DEL) | VAF 68/299 reads (23%) | catalogued as rs1226865525, CM162800, COSV57313178; called by mutect2, pindel, varscan2
- RBM15 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873450; called by muse, mutect2, varscan2
- RBM20 | c.1222del p.L408Sfs*17 | Frame Shift Del (DEL) | VAF 100/485 reads (21%) | catalogued as COSV65704142; called by mutect2, pindel, varscan2
- RBM28 | c.2242G>T p.A748S | Missense Mutation (SNP) | VAF 72/464 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV56162914; called by muse, mutect2, varscan2
- RBM33 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs750703227; called by muse, mutect2, varscan2
- RDH13 | c.250G>A p.G84R (on ENST00000415061 / NM_001145971.2; = p.G13R on NM_138412.4) | Missense Mutation (SNP) | VAF 99/327 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs370712723; called by muse, mutect2, varscan2
- REEP5 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as rs769331029; called by muse, mutect2
- REM2 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 187/518 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747619493, COSV99944740; called by muse, mutect2, varscan2
- RENBP | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.77); catalogued as rs781880066; called by muse, mutect2, varscan2
- RFWD3 | c.2073del p.F691Lfs*9 | Frame Shift Del (DEL) | VAF 141/450 reads (31%) | catalogued as rs867228258; called by mutect2, pindel, varscan2
- RGN | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 48/146 reads (33%) | catalogued as rs781832190; called by muse, mutect2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHAG | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 98/423 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100006899, COSV57704205; called by muse, mutect2, varscan2
- RHPN1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV56648097; called by muse, mutect2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RINT1 | c.839+1G>A p.X280_splice | Splice Site (SNP) | VAF 68/184 reads (37%) | catalogued as rs1042754408, COSV99994646; called by muse, mutect2, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 24/183 reads (13%) | catalogued as rs760343057; called by mutect2, varscan2
- RMND5B | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 119/281 reads (42%) | catalogued as rs749978415, COSV57744510; called by muse, mutect2, varscan2
- RNF103 | c.1678G>A p.V560I | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs112654860, COSV52893781, COSV52896281; called by muse, mutect2, varscan2
- RNF113A | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 113/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65097369; called by muse, mutect2, varscan2
- RNF128 | c.31dup p.W11Lfs*11 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF215 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.442); catalogued as rs751258397, COSV99306537; called by muse, mutect2, varscan2
- RNF225 | c.174del p.A59Pfs*? | Frame Shift Del (DEL) | VAF 81/281 reads (29%) | catalogued as rs1372594879; called by pindel, varscan2
- RNF26 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs779237173, COSV60990878; called by muse, mutect2, varscan2
- RNPEP | c.930del p.C311Afs*3 | Frame Shift Del (DEL) | VAF 60/448 reads (13%) | catalogued as rs1489424290; called by mutect2, varscan2
- ROBO1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369259928, COSV71397836; called by muse, mutect2, varscan2
- RPH3A | c.1213G>A p.D405N (on ENST00000389385 / NM_001143854.2; = p.D401N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1242895469; called by muse, mutect2, varscan2
- RPL9 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 61/422 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs137971690; called by muse, mutect2, varscan2
- RPS6KA4 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410769083; called by muse, mutect2, varscan2
- RPS6KA4 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs753090599, COSV53706679; called by muse, mutect2, varscan2
- RRAGC | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1434689954; called by muse, mutect2
- RRM2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.076); catalogued as rs766971538; called by muse, mutect2, varscan2
- RRNAD1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 89/292 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as rs1354251003; called by muse, mutect2, varscan2
- RRP8 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 32/221 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs747416881, COSV54448841; called by muse, mutect2, varscan2
- RSPH10B | c.68_69dup p.D24Lfs*4 | Frame Shift Ins (INS) | VAF 47/327 reads (14%) | catalogued as rs1356399611; called by mutect2, varscan2
- RTL6 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.065); catalogued as rs374819770; called by muse, mutect2, varscan2
- S100A16 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); catalogued as rs773071655, COSV64182898; called by muse, mutect2, varscan2
- SASS6 | c.214T>A p.F72I | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs143322383, COSV54926235; called by muse, mutect2, varscan2
- SBF1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as rs146850293; called by muse, mutect2, varscan2
- SCART1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.588); catalogued as rs1371815000, COSV62985999; called by muse, mutect2, varscan2
- SCN11A | c.1370del p.K457Rfs*15 | Frame Shift Del (DEL) | VAF 31/252 reads (12%) | catalogued as COSV56572200; called by mutect2, pindel, varscan2
- SDK1 | c.3812C>T p.T1271M | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286533820; called by muse, mutect2, varscan2
- SEC14L1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs759767028, COSV66721015; called by muse, mutect2, varscan2
- SEC16A | c.4282G>A p.V1428I | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs762456981; called by muse, mutect2, varscan2
- SELENOO | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 171/504 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs760796138, COSV66598783; called by muse, varscan2
- SEMA5A | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 164/493 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs772713334, CM165888, COSV66792946; called by muse, mutect2, varscan2
- SEMA5A | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 143/397 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs377224069, COSV101228556; called by muse, mutect2, varscan2
- SENP2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs749658679; called by muse, mutect2, varscan2
- SERGEF | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.407); catalogued as COSV99786829; called by muse, mutect2, varscan2
- SESN2 | c.722del p.P241Qfs*6 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as rs770146088, COSV53426876; called by mutect2, pindel, varscan2
- SFSWAP | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 118/401 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1287697193, COSV55523222; called by muse, mutect2, varscan2
- SH3RF3 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1300789857; called by muse, mutect2, varscan2
- SHANK1 | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760549131; called by muse, mutect2, varscan2
- SHANK3 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.595); catalogued as rs747137748; called by muse, mutect2, varscan2
- SHISA2 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.175); catalogued as rs776076069; called by muse, mutect2, varscan2
- SIPA1L1 | c.172del p.R58Efs*8 | Frame Shift Del (DEL) | VAF 85/188 reads (45%) | catalogued as rs1567251966; called by mutect2, varscan2
- SLC16A5 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs371143070; called by muse, mutect2, varscan2
- SLC24A1 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1400808532; called by muse, mutect2
- SLC26A5 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 105/320 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs150015080; called by muse, mutect2, varscan2
- SLC2A3 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.849); catalogued as COSV50004333; called by muse, mutect2
- SLC47A1 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 160/473 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200177585, COSV99565702; called by muse, mutect2, varscan2
- SLC66A2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1198213695; called by muse, mutect2, varscan2
- SLURP1 | c.158C>T p.T53M | Missense Mutation (SNP) | VAF 311/783 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs752253252, COSV55816549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD6 | c.1296del p.G433Afs*106 | Frame Shift Del (DEL) | VAF 50/204 reads (25%) | catalogued as rs751440011; called by mutect2, pindel, varscan2
- SMARCA5 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1440990938, COSV51642859; called by muse, mutect2, varscan2
- SMG1 | c.6173C>A p.P2058Q | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67170679; called by muse, mutect2, varscan2
- SMPD3 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 109/290 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs778977627; called by muse, mutect2, varscan2
- SMTNL1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs868169923; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs746109620; called by mutect2, varscan2
- SPACA5B | c.296A>T p.D99V | Missense Mutation (SNP) | VAF 114/863 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as rs1268688229; called by muse, mutect2, varscan2
- SPANXD | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 194/700 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs373261190, COSV65152935; called by muse, varscan2
- SPATA21 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 119/299 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs770095438; called by muse, mutect2
- SPINDOC | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 37/376 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.6); catalogued as rs759151440, COSV53692596; called by muse, mutect2, varscan2
- SPINT1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 249/353 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs538124649, COSV59801646; called by muse, mutect2, varscan2
- SPOCD1 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754159686, COSV57096251; called by muse, mutect2, varscan2
- SPOUT1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs777629140, COSV63510492; called by muse, mutect2, varscan2
- SPRED1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 245/326 reads (75%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as rs1348585688, COSV54434997; called by muse, mutect2, varscan2
- SPRED3 | c.544dup p.Q182Pfs*238 | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | catalogued as rs774610521; called by mutect2, varscan2
- SQSTM1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757212984, CM041449, COSV52972344; called by muse, mutect2, varscan2
- SS18L1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 110/333 reads (33%) | catalogued as COSV59213598; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | catalogued as rs753297385; called by mutect2, varscan2
- SSC5D | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781774065; called by muse, mutect2, varscan2
- SSH1 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 135/363 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs1223198563; called by muse, mutect2, varscan2
- SSTR4 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375423682; called by muse, mutect2, varscan2
- SSTR4 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV54797485; called by muse, mutect2
- ST8SIA5 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 147/415 reads (35%) | PolyPhen probably damaging (0.998); catalogued as rs770525648; called by muse, mutect2, varscan2
- STARD8 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779051740, COSV52926228; called by muse, mutect2, varscan2
- STAT2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV58474596; called by muse, mutect2, varscan2
- STX11 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs151047913, COSV62448785; called by muse, mutect2, varscan2
- SUDS3 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.939); catalogued as rs771567083, COSV64348701; called by muse, mutect2, varscan2
- SUPT20HL1 | c.1625C>T p.A542V | Missense Mutation (SNP) | VAF 256/663 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs935856190; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2450_2452dup p.Q817dup | In Frame Ins (INS) | VAF 104/337 reads (31%) | catalogued as rs755894037; called by mutect2, varscan2
- SYNE1 | c.16147_16149del p.E5383del (on ENST00000367255 / NM_182961.4; = p.E5312del on NM_033071.3) | In Frame Del (DEL) | VAF 63/189 reads (33%) | catalogued as rs1563045771; called by mutect2, pindel, varscan2
- SYNGR4 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 30/158 reads (19%) | catalogued as COSV61225884; called by muse, mutect2, varscan2
- SYT9 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs374567594; called by muse, mutect2, varscan2
- TAF1C | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs766098348, COSV58987844; called by muse, mutect2, varscan2
- TAF8 | c.683_685del p.L228del | In Frame Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs746056203; called by pindel, varscan2
- TAOK2 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1020575217, COSV99665205; called by muse, mutect2, varscan2
- TAOK3 | c.2608C>T p.R870* | Nonsense Mutation (SNP) | VAF 73/237 reads (31%) | catalogued as COSV66826843; called by muse, mutect2, varscan2
- TAPBPL | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1200893805; called by muse, mutect2
- TBC1D1 | c.3442C>T p.R1148W | Missense Mutation (SNP) | VAF 202/595 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs573080470, COSV54714209; called by muse, mutect2, varscan2
- TBC1D12 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs368922760; called by muse, mutect2, varscan2
- TBC1D2B | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1284284086, COSV56039550; called by muse, mutect2
- TBL1X | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 94/293 reads (32%) | catalogued as COSV54275809, COSV54277470; called by muse, mutect2, varscan2
- TDRD3 | c.1216del p.R406Efs*28 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as COSV52161962; called by mutect2, pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 29/165 reads (18%) | catalogued as rs763321097; called by mutect2, varscan2
- TELO2 | c.682+1G>A p.X228_splice | Splice Site (SNP) | VAF 29/163 reads (18%) | catalogued as rs779227414; called by muse, mutect2, varscan2
- TEPSIN | c.1350del p.G452Afs*72 | Frame Shift Del (DEL) | VAF 101/303 reads (33%) | catalogued as rs745976991, COSV56142035; called by mutect2, varscan2
- TGFBI | c.1502dup p.M502Nfs*15 | Frame Shift Ins (INS) | VAF 34/156 reads (22%) | catalogued as rs771515402; called by mutect2, varscan2
- THEMIS2 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1212189183, COSV61077639; called by muse, mutect2, varscan2
- THSD7A | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377188011, COSV70259431; called by muse, mutect2, varscan2
- THSD7A | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as rs557343659; called by muse, mutect2, varscan2
- TJP3 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 73/197 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs373989858; called by muse, mutect2, varscan2
- TLR7 | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV101027992; called by muse, mutect2
- TMBIM1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV50310785; called by muse, mutect2, varscan2
- TMC8 | c.1454C>A p.T485N | Missense Mutation (SNP) | VAF 18/637 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100573744; called by muse, mutect2
- TMEM132B | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 15/444 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs867009286, COSV54756521; called by muse, mutect2
- TMEM132C | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs573672723, COSV59421435; called by muse, mutect2, varscan2
- TMEM63B | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52481360; called by muse, mutect2, varscan2
- TMEM81 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 90/232 reads (39%) | catalogued as rs148879722; called by muse, mutect2, varscan2
- TMEM97 | c.528del p.K176Nfs*188 | Frame Shift Del (DEL) | VAF 26/92 reads (28%) | catalogued as rs781830688; called by mutect2, varscan2
- TNFAIP3 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 158/508 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1373396587, COSV99397134; called by muse, mutect2, varscan2
- TNR | c.3520G>A p.G1174R | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1279570596, COSV99689559, COSV99690585; called by muse, mutect2, varscan2
- TNS3 | c.2358del p.Q787Sfs*33 | Frame Shift Del (DEL) | VAF 85/318 reads (27%) | catalogued as COSV60787512; called by mutect2, pindel, varscan2
- TONSL | c.2106del p.S703Lfs*140 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs34149392; called by mutect2, pindel, varscan2
- TPI1 | c.700G>A p.V234I (on ENST00000229270; = p.V197I on NM_000365.6) | Missense Mutation (SNP) | VAF 156/436 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs782801396; called by muse, mutect2, varscan2
- TRANK1 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs749482435; called by muse, varscan2
- TRBV28 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs776778885; called by muse, mutect2, varscan2
- TRERF1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs1486845394; called by muse, mutect2
- TRIM38 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs755536630, COSV100837624; called by muse, mutect2, varscan2
- TRIM45 | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs750775744; called by muse, mutect2, varscan2
- TRIM46 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs573947622, COSV55279188; called by muse, mutect2, varscan2
- TRIM51 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776212732, COSV99069571; called by muse, mutect2, varscan2
- TRIM55 | c.999A>T p.E333D | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1168265051, COSV52544131; called by muse, mutect2
- TRIOBP | c.3422G>T p.R1141M | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV60375561; called by muse, mutect2, varscan2
- TRPC7 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.727); catalogued as COSV61457795; called by muse, mutect2, varscan2
- TSEN54 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 169/456 reads (37%) | catalogued as rs201775186, COSV99390135; called by muse, mutect2, varscan2
- TSG101 | c.794del p.K265Rfs*13 | Frame Shift Del (DEL) | VAF 104/472 reads (22%) | catalogued as COSV52648802; called by pindel, varscan2
- TSPAN17 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); catalogued as rs754616228; called by muse, mutect2, varscan2
- TTC12 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 132/333 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs559449784, COSV100133305; called by muse, mutect2, varscan2
- TTC23 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs753635041; called by muse, mutect2, varscan2
- TTLL10 | c.886G>A p.E296K (on ENST00000379289 / NM_001130045.2; = p.E223K on NM_153254.3) | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs1183153253, COSV64960905; called by muse, mutect2
- TTN | c.31736C>T p.A10579V (on ENST00000591111; = p.A9652V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/175 reads (26%) | PolyPhen benign (0.003); catalogued as COSV59936707; called by muse, mutect2, varscan2
- TUT4 | c.2135C>T p.T712M | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs780205463, COSV57121247; called by muse, mutect2, varscan2
- U2SURP | c.2598del p.K866Nfs*10 | Frame Shift Del (DEL) | VAF 58/198 reads (29%) | catalogued as COSV67533295; called by mutect2, pindel, varscan2
- UBE3A | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs1384065874; called by muse, mutect2, varscan2
- UBE4A | c.2237G>A p.R746H (on ENST00000252108 / NM_001204077.2; = p.R753H on NM_004788.4) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as rs782596932, COSV52802949; called by muse, mutect2, varscan2
- UFSP1 | c.196dup p.D66Gfs*38 | Frame Shift Ins (INS) | VAF 46/165 reads (28%) | catalogued as rs751446699; called by mutect2, varscan2
- UNC13A | c.2321C>T p.T774M | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769897194, COSV53208825; called by muse, mutect2, varscan2
- UNC13D | c.3151G>A p.G1051R | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1232542382; called by muse, mutect2
- UNC45B | c.1151+1G>A p.X384_splice | Splice Site (SNP) | VAF 36/96 reads (38%) | catalogued as rs371932269; called by muse, mutect2, varscan2
- URB1 | c.6094C>T p.R2032* | Nonsense Mutation (SNP) | VAF 47/147 reads (32%) | catalogued as rs751349717; called by muse, mutect2, varscan2
- URB1 | c.4031G>A p.R1344H | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs374160696; called by muse, mutect2, varscan2
- USH2A | c.7168G>A p.G2390R | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.177); catalogued as rs376983577, CM149922; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- USP22 | c.941G>A p.C314Y | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54947532; called by muse, mutect2, varscan2
- USP24 | c.985G>A p.V329M | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs764632901; called by muse, mutect2, varscan2
- USP29 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.917); catalogued as COSV54141744; called by muse, mutect2, varscan2
- USP32 | c.3362C>T p.A1121V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.788); catalogued as rs202121527, COSV56266854; called by muse, mutect2, varscan2
- VIPAS39 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as rs143222977; called by muse, mutect2, varscan2
- VIPR2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs370731634; called by muse, mutect2, varscan2
- VIRMA | c.4918C>T p.R1640C | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278500361, COSV52582824; called by muse, mutect2, varscan2
- VPS13B | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs780180063; called by muse, mutect2, varscan2
- VPS13D | c.10639A>G p.T3547A | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.306); catalogued as COSV99169671; called by muse, mutect2, varscan2
- VPS9D1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101231973; called by muse, mutect2, varscan2
- WDFY3 | c.5899C>T p.R1967W | Missense Mutation (SNP) | VAF 149/433 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766875579, COSV55695997; called by muse, mutect2, varscan2
- WDFY4 | c.4970G>A p.R1657H | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.374); catalogued as rs372093445; called by muse, varscan2
- WDR33 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs772360144; called by muse, mutect2, varscan2
- WDR4 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as rs779710658; called by muse, mutect2, varscan2
- WDR7 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); catalogued as rs753471141; called by muse, mutect2, varscan2
- WDR75 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1486562545, COSV59105932; called by muse, mutect2
- WDR81 | c.4828G>A p.V1610M (on ENST00000409644 / NM_001163809.2; = p.V559M on NM_152348.4) | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs773453878; called by muse, mutect2
- WDR97 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 215/556 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as rs1273364206; called by muse, mutect2, varscan2
- WNK2 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs775049337; called by muse, mutect2, varscan2
- WNK2 | c.5128G>A p.V1710I (on ENST00000297954 / NM_001282394.1; = p.V1673I on NM_006648.3) | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs140544829; called by muse, mutect2, varscan2
- XAB2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as rs149004243; called by muse, varscan2
- XIRP2 | c.5316del p.D1773Mfs*5 (on ENST00000628543; = p.D1948Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | catalogued as rs760810271; called by mutect2, varscan2
- XRN1 | c.2012dup p.L671Ffs*30 | Frame Shift Ins (INS) | VAF 48/140 reads (34%) | catalogued as rs1197134126; called by mutect2, varscan2
- ZC3H3 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs546501323; called by muse, mutect2, varscan2
- ZC3H7B | c.583-1G>T p.X195_splice | Splice Site (SNP) | VAF 42/226 reads (19%) | catalogued as COSV60961778; called by muse, mutect2, varscan2
- ZCCHC17 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs756086562; called by muse, mutect2, varscan2
- ZFPL1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775334314; called by muse, mutect2
- ZIC4 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 86/306 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs781047867; called by muse, mutect2, varscan2
- ZMYND19 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV53021484; called by muse, mutect2, varscan2
- ZNF180 | c.1939C>T p.R647* | Nonsense Mutation (SNP) | VAF 57/145 reads (39%) | catalogued as rs377043880; called by muse, mutect2, varscan2
- ZNF234 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70603981; called by muse, mutect2, varscan2
- ZNF236 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 131/412 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1286660473, COSV53488485; called by muse, mutect2, varscan2
- ZNF407 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 105/341 reads (31%) | catalogued as COSV99996408; called by muse, mutect2, varscan2
- ZNF407 | c.5507C>T p.A1836V | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs755809901, COSV100224406; called by muse, mutect2, varscan2
- ZNF417 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 132/521 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs747020640; called by muse, mutect2, varscan2
- ZNF449 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs781985440; called by muse, mutect2
- ZNF496 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 70/778 reads (9%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs188968543; called by muse, mutect2
- ZNF506 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 80/302 reads (26%) | catalogued as COSV101475655; called by muse, mutect2, varscan2
- ZNF536 | c.3560C>A p.P1187Q | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV104416731; called by muse, mutect2, varscan2
- ZNF638 | c.3912del p.G1305Vfs*22 | Frame Shift Del (DEL) | VAF 43/158 reads (27%) | catalogued as rs1196097264; called by mutect2, varscan2
- ZNF672 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs375274358; called by muse, varscan2
- ZNF697 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70284368; called by muse, mutect2, varscan2
- ZNF710 | c.1461C>T p.G487= | Splice Region (SNP) | VAF 18/131 reads (14%) | catalogued as rs758028766; called by muse, mutect2, varscan2
- ZNF93 | c.513dup p.P172Tfs*12 | Frame Shift Ins (INS) | VAF 26/62 reads (42%) | catalogued as rs775444781; called by mutect2, varscan2
- ZSCAN10 | c.341C>T p.A114V (on ENST00000252463; = p.A169V on NM_032805.3) | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770550691; called by muse, mutect2
- A1BG | c.1460dup p.V488Cfs*56 | Frame Shift Ins (INS) | VAF 38/347 reads (11%) | called by mutect2, pindel, varscan2
- AASS | c.2336T>C p.L779S | Missense Mutation (SNP) | VAF 27/422 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ABCA12 | c.4313A>G p.H1438R (on ENST00000272895 / NM_173076.3; = p.H1120R on NM_015657.3) | Missense Mutation (SNP) | VAF 75/442 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA6 | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- ABCB7 | c.937C>T p.R313W (on ENST00000373394 / NM_001271696.3; = p.R314W on NM_004299.6) | Missense Mutation (SNP) | VAF 43/517 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- ABCG4 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2
1,368 further variants in this file (662 protein-altering or splice-affecting, 459 silent, 247 other) are not listed here.
